Gene-level copy-number profile of tumor specimen TCGA-AX-A3G7-01A from TCGA case TCGA-AX-A3G7, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 71.7 years (26,187 days).
Specimen TCGA-AX-A3G7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.46c06b3c-05fe-43a3-b367-260f425d485e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AX-A3G7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5eb338ca-5339-49fd-a4bf-b2db1eac4106

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 10,147; copy number 2: 46,028; copy number 3: 3,188; copy number 4: 342; copy number 5: 99; copy number 6: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AX-A3G7-01A-12D-A20R-01): tumor purity 0.73, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:31,272,013–31,346,190, 5 genes: OMG, EVI2B, AC134669.1, EVI2A, AK4P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 104 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:51,707,068–52,579,237, 49 genes, copy number 5 (within-gene range 2–5): GRM2, IQCF6, AC097636.1, IQCF4P, IQCF3, IQCF2, RN7SL504P, IQCF5-AS1, IQCF5, IQCF1, AC115284.4, RRP9, PARP3, AC115284.2, GPR62, PCBP4, AC115284.1, ABHD14B, ABHD14A, ABHD14A-ACY1, ACY1, RPL29, AC115284.3, DUSP7, POC1A, AC097637.3, ALDOAP1, ALAS1, AC097637.2, TLR9, AC097637.1, TWF2, AC006252.1, PPM1M, WDR82, MIRLET7G, GLYCTK, GLYCTK-AS1, MIR135A1, DNAH1, PPP2R5CP, BAP1, PHF7, SEMA3G, TNNC1, NISCH, STAB1, NT5DC2, SMIM4.
- chr3:52,551,846–52,560,707, 2 genes, copy number 5: RNU6-856P, RNU6ATAC16P.
- chr3:168,858,659–169,038,416, 5 genes, copy number 6: RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997.
- chr8:105,546,089–106,060,524, 1 gene, copy number 5 (within-gene range 2–5): ZFPM2-AS1.
- chr8:105,826,570–106,272,902, 5 genes, copy number 5: AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2.
- chr19:14,732,392–15,584,709, 42 genes, copy number 5 (within-gene range 2–5): ADGRE2, OR7C1, AC005255.1, OR7A5, OR7A10, OR7A8P, OR7A2P, OR7A17, OR7A18P, OR7A1P, OR7A3P, OR7A11P, OR7A15P, OR7C2, SLC1A6, CCDC105, CASP14, OR1I1, SYDE1, ILVBL, AC003956.1, OR10B1P, RNU6-782P, NOTCH3, MIR6795, AC004257.1, EPHX3, BRD4, AC005776.1, AC005776.2, AKAP8, AC005785.1, AKAP8L, AC005785.2, AC006128.1, WIZ, MIR1470, RASAL3, PGLYRP2, CYP4F22, AC011492.1, CYP4F23P.

Autosomal genes at a single copy (total copy number 1): 10,147. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
